CCDI case PBCLSN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2411cbbe-acb8-48e0-a32a-cb99541b780e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,035 days).

Biospecimens (4 samples)
- Samples 0DUYNR, 0DUYNW (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUYNT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4IZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
